Somatic mutation profile of tumor specimen 0DRKKO from CCDI case PBCGKZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,845 days).
Specimen 0DRKKO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03d7d3a2-daa3-4b45-9735-6d76149b6b10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRKKV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/281529d2-29a8-4a40-ae6b-4f88ebabded4

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM122C | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 36/608 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- NPC1L1 | c.1061C>A p.T354N | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, mutect2
- PPARGC1B | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 114/476 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF445 | c.834C>A p.T278= | Silent (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
